Somatic mutation profile of tumor specimen TCGA-EJ-5494-01A (aliquot TCGA-EJ-5494-01A-01D-1576-08) from TCGA case TCGA-EJ-5494, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.9 years (18,596 days).
Specimen TCGA-EJ-5494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2380e0b7-769a-4dc6-9a5f-a67f7e752cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5494-10A (Blood Derived Normal), aliquot TCGA-EJ-5494-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a29aaf07-084f-4c6b-8e47-225b3322304e

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs753564161, COSV64196090; called by muse, mutect2
- CDK19 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as COSV60450143; called by muse, mutect2, varscan2
- CRB2 | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV63503749; called by muse, mutect2
- CRB2 | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV63503759; called by muse, mutect2
- CUL2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66079482; called by muse, mutect2
- DPH1 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs201399054; called by muse, mutect2
- EZHIP | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV57956394, COSV57956541; called by muse, mutect2, varscan2
- FAM83C | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs369109150, COSV100981516; called by muse, mutect2
- KRT1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779743242, COSV52867410; called by muse, mutect2
- MEN1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775922507, COSV53644605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54238709; called by muse, mutect2, varscan2
- NEUROD6 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51772059; called by muse, mutect2, varscan2
- PCDHB7 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 27/623 reads (4%) | catalogued as rs782652788, COSV50754277; called by muse, mutect2
- SALL1 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51754374; called by muse, mutect2
- SH3GLB2 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1402384809, COSV65331153; called by muse, mutect2, varscan2
- SIPA1L3 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55916540; called by muse, mutect2
- TBX18 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs1416893079, COSV63735937; called by muse, mutect2
- TFAP2D | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs373515669, COSV50419258; called by muse, mutect2, varscan2
- UBR3 | c.5140A>G p.I1714V | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1044789702, COSV55851613; called by muse, mutect2, varscan2
- TMEM30A | c.684_685+47del p.X228_splice | Splice Site (DEL) | VAF 54/252 reads (21%) | called by mutect2, pindel
- CA1 | c.351C>T p.A117= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs779414954, COSV56278920; called by muse, mutect2
- GHDC | c.1317C>T p.Y439= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as rs756837467, COSV99511543; called by muse, mutect2, varscan2
- LIMCH1 | c.777G>A p.E259= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as rs1276044106, COSV58286779; called by muse, mutect2
- LRRC66 | c.1266C>T p.N422= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as rs1275067237, COSV58634416; called by muse, mutect2
- PCDHA4 | c.2157C>T p.T719= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV63539269; called by muse, mutect2
